Surgical pathology report (de-identified scan), TCGA case TCGA-KL-8330, project TCGA-KICH (Kidney Chromophobe), tissue source site MSKCC, specimen TCGA-KL-8330-01A (Primary Tumor).

[page 1 of 2]
Clinical Diagnosis & History:

with right renal mass.

Specimens Submitted:

1: SP: Right kidney & adrenal gland

2: SP: Right paracaval nodes

DIAGNOSIS:

- 1) KIDNEY AND ADRENAL GLAND, RIGHT; RADICAL NEPHRECTOMY:
- RENAL CELL CARCINOMA, CHROMOPHOBE TYPE.
- THE TUMOR GREATEST DIAMETER IS 18 CM.
- THE TUMOR IS CONFINED WITHIN THE RENAL CAPSULE.
- NO INVASION OF THE RENAL VEIN IS IDENTIFIED.
- ALL SURGICAL MARGINS ARE FREE OF TUMOR.
- THE NON-NEOPLASTIC KIDNEY IS UNREMARKABLE.
- THE ADRENAL GLAND IS UNREMARKABLE.
- 2) LYMPH NODES, RIGHT PARACAVAL; EXCISION:
- EIGHT BENIGN LYMPH NODES (0/8).

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Special Studies:

Result

Special Stain

Comment

RECUT

RECUT

RECUT

1) The specimen is received fresh, labeled "Right Kidney and Adrenal Gland". It consists of a kidney, adrenal gland and tumor. The specimen measures 19 cm (superior-inferior) x 14.5 cm (anterior-posterior) x 17.2 cm (lateral). The specimen weighs 1,800 grams. The adrenal gland is disrupted and measures 8.7 x 3.1 x 0.7 cm. The ureter measures 6.5 x 0.6 x 0.4 cm. The tumor measures 18 x 15 x 13.5 cm. The adrenal gland appears to be uninvolved by tumor. On the cross section, tumor has a centrally located scar and appears to be light mahogany in color. There are some areas of hemorrhagic. The tumor arises from the superior pole of the kidney and appears to be well-demarcated. The kidney measures 9.5 x 7.5 x 6 cm. Gross photographs and are taken. The tumor does not involve the kidney pelvis and it has a thin, fibrous membrane around it. The tumor is very friable. Representative sections are submitted.

[page 2 of 2]
Summary of Sections:

MA – ureteral vascular margins and representative sections of adrenal gland

C – section of tumor with capsule

K – section of uninvolved kidney

P – section of kidney pelvic

T – sections of the tumor

2) The specimen is received in formalin, labeled "Right Paracaval Nodes". It consists of a 4.0 x 2.5 x 1.5 cm aggregate of fibrofatty tissue fragments with multiple lymph nodes dissected ranging from 0.9 to 2.8 cm in greatest dimension. The largest two lymph nodes are bisected and each is submitted in a separate cassette. The remainder of the lymph nodes are entirely submitted.

Summary of Sections:

BLN1 – first bisected lymph node

BLN2 – second bisected lymph node

LN – remainder of the lymph nodes

Summary of Sections:

Part 1: SP: Right kidney & adrenal gland

Block	Sect. Site	PCs
1	C	1
1	K	1
1	MA	4
1	P	1
7	T	7

Part 2: SP: Right paracaval nodes

Block	Sect. Site	PCs
1	BLN1	2
1	BLN2	2
2	LN	4

Source: NCI Genomic Data Commons file 970c0ace-96ab-410c-994a-b5ae4bce583b (TCGA-KL-8330.1E3DF59F-DD7C-4718-BE8B-CE7C0ADCE23C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).